TCGA case TCGA-MB-A5Y8 — Sarcoma (TCGA-SARC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Soft Tissue Tumors and Sarcomas, NOS; Primary site: Connective, subcutaneous and other soft tissues; Tissue source site: University of Minnesota. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/49fd3506-eb64-4ecd-a367-303b1d7a7fc9

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Country of residence at enrollment: United States; Age at index: 60 years; Vital status: Alive.

Diagnoses (1)
1. Undifferentiated sarcoma: ICD-O-3 morphology code: 8805/3; ICD-10 code: C49.2; Tissue or organ of origin: Connective, subcutaneous and other soft tissues of lower limb and hip; Site of resection or biopsy: Connective, subcutaneous and other soft tissues of lower limb and hip; Classification of tumor: primary; Age at diagnosis: 60.5 years (22,115 days); Year of diagnosis: 2012; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Residual disease: R0.
   Pathology details: Measurement type: Radiologic; Tumor burden: 10.
   Pathology details: Measurement type: Radiologic; Measurement unit: Centimeters; Tumor depth measurement: 3; Tumor length measurement: 4; Tumor width measurement: 3.
   Pathology details: Measurement type: Pathologic; Measurement unit: Centimeters; Tumor depth measurement: 2.5; Tumor length measurement: 12.8; Tumor width measurement: 3.5.
   Pathology details: Consistent pathology review: Yes; Margin status: Uninvolved; Necrosis present: No.
   Pathology details: Measurement type: Pathologic; Tumor burden: 18.8.

Follow-up (2 entries)
- Days to follow up: 253 days; Disease response: Tumor Free.
- Days to follow up: 773 days (2.1 years); Disease response: Tumor Free.

Biospecimens (4 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-MB-A5Y8-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT; Initial weight: 380 mg.
  Slide TCGA-MB-A5Y8-01A-01-TSA: Section location: Top; Percent tumor cells: 85; Percent tumor nuclei: 100; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 15; Percent lymphocyte infiltration: 2; Percent monocyte infiltration: 1; Percent neutrophil infiltration: 0.
- Sample TCGA-MB-A5Y8-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Samples TCGA-MB-A5Y8-10A, TCGA-MB-A5Y8-10B (2 with the same recorded description): Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Prospective collection: Yes; Retrospective collection: No; History neoadjuvant treatment: No; Tumor status: Tumor free; New tumor event diagnosis indicator: No.
- Primary pathology: Histologic diagnosis: Undifferentiated Pleomorphic Sarcoma (UPS); Margin status: Negative; Tumor total necrosis: 0% (no necrosis or no mention of necrosis).
- Primary pathology, Tumor tissue sites: Submitted tumor site: Lower Extremity - Lower leg/calf.
- Primary pathology, Tumor sizes, Tumor size: Lesion radiologic length: 4; Lesion radiologic width: 3; Lesion radiologic depth: 3.
- Follow-up form: Lost to follow-up: No; Tumor status: Tumor free; Treatment outcome at TCGA followup: Complete Response; New tumor event diagnosis indicator: No.
- Drug treatment 1: Treatment on clinical trial: No; Days from index date to pharmaceutical treatment started: 248; Pharmaceutical therapy drug name: Doxil; Pharmaceutical treatment ongoing indicator: Yes.
- Drug treatment 1, Therapy types: Pharmaceutical therapy type: Chemotherapy.
- Drug treatment 2: Treatment on clinical trial: No; Days from index date to pharmaceutical treatment started: 248; Pharmaceutical therapy drug name: ifosfamide; Pharmaceutical treatment ongoing indicator: Yes.
- Radiation treatment: Days from index date to radiation therapy started: 71; Days from index date to radiation therapy ended: 115; Radiation therapy type: External; Radiation total dose: 5800; Radiation adjuvant units: cGy; Radiation adjuvant fractions total: 6; Radiation therapy site: Primary Tumor Field; Radiation therapy ongoing indicator: No.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 773 days; disease-specific survival: no event (censored), 773 days; disease-free interval: no event (censored), 773 days; progression-free interval: no event (censored), 773 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-MB-A5Y8-01A-11D-A29M-01): tumor purity 0.77, ploidy 1.75, whole-genome doublings 0.
